FM case AD5590 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/63a05c9f-a1a6-4ef7-9833-c7f2f3d82c65

Male, 60.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
